Surgical pathology report (de-identified scan), TCGA case TCGA-55-7728, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7728-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

COPY TO: [REDACTED]

Pre-Op Diagnosis
Lung cancer
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Five parts

Container labeled [REDACTED] - level 7 lymph node left lung" has a 1.0 x 0.9 x 0.4 cm nodular portion of gray-black fleshy tissue which is bisected and entirely submitted in a single cassette.

Container labeled [REDACTED] - level 10 lymph node left lung" has two nodular portions of rubbery gray-pink fleshy tissue, 1.5 x 1.0 x 0.7 cm and 1.6 x 1.0 x 0.7 cm. Each has a mottled fleshy gray-black cut surface. Also received in the same container are 1.0 x 0.7 x 0.4 cm of similar tissue fragments. Each of the nodules is sectioned and individually submitted labeled A-B. Remaining tissue fragments are submitted labeled C.

Container labeled [REDACTED] - left upper lobe" has a previously partially inked, partially sectioned portion of recognizable pulmonary parenchyma grossly consistent with left upper lobe of lung. The specimen as received weighs 126 grams and measures 16.7 x 9.5 x 2.9 cm. The margin of resection is bifurcation of the tertiary bronchi with an adjacent 1.5 x 1.0 x 0.7 cm fleshy gray-black nodule. The pleura is slightly wrinkled gray-pink and moderately anthracotic streaked. On the posterior aspect of the mid region is a partially sectioned previously inked 3.5 x 3.2 cm area of umbilicated induration. The specimen is partially sectioned in

page 1 of 3

[page 2 of 3]
this region to reveal an underlying 3.5 x 2.9 x up to 1.6 cm somewhat fleshy focally gritty gray-tan fibrotic lesion which extends to but does not grossly appear to extend through the pleura. This is seen at its nearest point 2.3 cm from the nearest bronchial margin. An apparent bronchial connection is identified. On sectioning, the remaining parenchyma reveals spongy congested parenchyma with minimal anthracotic streaking. No additional gross lesions are identified. Also received in the same container are two tissue cassettes. The first is a red cassette labeled [REDACTED] and the second is a gray cassette labeled "good". Representative sections of the tissue are submitted labeled as follows: A - shaved bronchial margin; B - peribronchial nodule sectioned; C-G - lesion and surrounding tissue with pleura inked; H - grossly uninvolved parenchyma.

Container labeled [REDACTED] 4 - level 9 lymph node left lung" has four irregular portions of gray-yellow fibroadipose tissue, from 1.0 x 0.8 x 0.5 cm to 2.0 x 2.0 x 0.8 cm. Each is sectioned and individually submitted in four cassettes.

Container labeled [REDACTED] 5 - level 5 lymph node left lung" has a 1.6 x 0.8 x 0.5 cm elongated nodular portion of gray-tan fleshy tissue with a mottled gray-black fleshy cut surface. The bisected nodule is entirely submitted in a single cassette.

Microscopic Description: [REDACTED]
The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Lymph node, level 7, left lung (biopsy):

Reactive sinus histiocytosis, mild reactive lymphoid hyperplasia and anthracosilicosis, no metastatic carcinoma identified within one lymph node (0/1). [REDACTED]

Lymph nodes, level 10, left lung (biopsy):

Reactive sinus histiocytosis, mild lymphoid hyperplasia and anthracosilicosis, no metastatic carcinoma identified within six lymph nodes (0/6). [REDACTED]

Lymph nodes, level 9, left lung (biopsy):

Reactive sinus histiocytosis, lymphoid hyperplasia and anthracosilicosis, no metastatic carcinoma identified within four lymph nodes (0/4). [REDACTED]

Lymph node, level 5, left lung (biopsy):

Reactive sinus histiocytosis, lymphoid hyperplasia and anthracosilicosis, no metastatic carcinoma identified within one lymph node (0/1). [REDACTED]

Lung, left upper lobe (lobectomy):

Specimen integrity: Intact

Specimen laterality: Left side

Tumor site: Left upper lobe

Tumor characteristics:

Histologic type: Mucinous adenocarcinoma

Histologic grade: Well differentiated

Tumor site: Left upper lobe

Tumor focality: Unifocal

Tumor size: 3.5 x 3.2 x 1.6 cm in greatest dimensions

Visceral pleural invasion: Not identified (see comment)

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified

Treatment effect: Unknown

[page 3 of 3]
Tumor extension: Not identified

Surgical margin status:

Bronchial margin: No carcinoma identified, tumor distance 2.3 cm

Parenchymal margin: Not applicable

Pleural surface: No carcinoma identified, less than 1 mm from pleural surface

Lymph node status:

Total number of bronchial lymph nodes: 1

Total number of lymph nodes containing metastatic carcinoma: 0 (0/1)

See above diagnoses for other lymph nodes. [REDACTED]

Other findings:

Emphysematous changes. [REDACTED]

Areas of subpleural fibrosis associated with carcinoma (see comment).

Stage: pT2a N0 SPC-A

CPT: 88309, 88304 x 4, 88342 x 5,

Comments

Sections of the tumor show a well differentiated mucinous adenocarcinoma. Focally, in one residual bronchus, an area of in situ adenocarcinoma is identified. In addition, some subpleural fibrosis is present suggesting that this is a primary adenocarcinoma as opposed to a metastatic adenocarcinoma. A panel of immunohistochemical stains is performed including CK7, CK20, CDX2, and TTF1 (with appropriate positive and negative controls). The neoplastic cells are strongly positive for CK7. The neoplastic cells demonstrate some scattered focal positive stain for CK20. The neoplastic cells demonstrate focal weakly positive staining TTF1. In addition, the neoplastic cells demonstrate a rare focal positive staining cell for CDX2.

This demonstrates a well differentiated mucinous adenocarcinoma. The subpleural fibrosis would suggest this represents a primary lung neoplasm, however, the immunohistochemical stains are equivocal and therefore the possibility of a metastatic lesion cannot be fully excluded on histologic grounds alone. Clinical correlation and follow up is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by [REDACTED] who concurs with the diagnosis.

This test has been finalized at the [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED]. [REDACTED] is qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Source: NCI Genomic Data Commons file 7442f216-02ba-453e-a58a-bc91fba0eaf0 (TCGA-55-7728.D12721B3-53DC-47E8-A9C2-03343EC7A4BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).